Somatic mutation profile of tumor specimen 0DLIFP from CCDI case PBBZHP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 3.3 years (1,203 days).
Specimen 0DLIFP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7231f7b6-bf6b-4e0c-bd0f-a5cae23d5c4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLIF9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c919e102-e6cc-4c22-91a2-4558d5029eb2

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, 3'UTR 3, Silent 3, Splice Region 2, Intron 2, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 274/594 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTAGE1 | c.1840A>G p.M614V | Missense Mutation (SNP) | VAF 146/617 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs375980034; called by muse, mutect2, varscan2
- CUX1 | c.3487G>T p.D1163Y | Missense Mutation (SNP) | VAF 250/697 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52894485; called by muse, mutect2, varscan2
- IL17RB | c.945C>T p.H315= | Splice Region (SNP) | VAF 213/761 reads (28%) | catalogued as rs201029803, COSV99860976; called by muse, mutect2, varscan2
- PREB | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 184/446 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs749595387; called by muse, mutect2, varscan2
- RHOBTB2 | c.-10-6C>T | Splice Region (SNP) | VAF 213/826 reads (26%) | catalogued as rs757703083; called by muse, mutect2, varscan2
- TGFBR3 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 60/1210 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1172763410; called by muse, mutect2
- TIGIT | c.358G>T p.G120W | Missense Mutation (SNP) | VAF 145/369 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101048128; called by muse, mutect2, varscan2
- C8orf48 | c.396G>T p.L132F | Missense Mutation (SNP) | VAF 226/1042 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA1S | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 345/816 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CELSR2 | c.5153C>A p.S1718Y | Missense Mutation (SNP) | VAF 169/371 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAM98B | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 98/326 reads (30%) | called by muse, mutect2, varscan2
- MAP3K6 | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 190/433 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.221); called by muse, varscan2
- OR14I1 | c.298T>A p.Y100N | Missense Mutation (SNP) | VAF 207/484 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- RNPEP | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 214/511 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TENM4 | c.3460dup p.R1154Kfs*9 | Frame Shift Ins (INS) | VAF 311/1152 reads (27%) | called by mutect2, varscan2
- PPFIA2 | c.3024G>T p.P1008= | Silent (SNP) | VAF 204/985 reads (21%) | called by muse, mutect2, varscan2
- PRND | c.39C>A p.V13= | Silent (SNP) | VAF 247/986 reads (25%) | catalogued as COSV59896748; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1374G>A p.E458= | Silent (SNP) | VAF 341/1049 reads (33%) | catalogued as COSV60873301; called by muse, mutect2, varscan2
- GNPTAB | c.*37_*47del | 3'UTR (DEL) | VAF 163/512 reads (32%) | called by mutect2, varscan2
- KCNC4 | c.*749G>A | 3'UTR (SNP) | VAF 101/301 reads (34%) | catalogued as rs541105415; called by muse, mutect2, varscan2
- OSCAR | c.*417G>A | 3'UTR (SNP) | VAF 118/448 reads (26%) | called by muse, mutect2, varscan2
- UNC13A | c.4273-32G>T | Intron (SNP) | VAF 30/126 reads (24%) | called by muse, mutect2, varscan2
- ZNF408 | c.393-77G>T | Intron (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
